Somatic mutation profile of tumor specimen C3N-02529-01 (aliquot CPT0147480010) from CPTAC case C3N-02529, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 79.5 years (29,049 days).
Specimen C3N-02529-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f928a855-80c8-4555-9690-ebde10d2d48e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02529-71 (Blood Derived Normal), aliquot CPT0147510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bdedcd9-6bc4-40df-82b3-90496834987f

The open-access MAF lists 170 somatic variants for this specimen: 109 protein-altering or splice-affecting, 42 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 42, Intron 13, Nonsense Mutation 12, 5'UTR 2, 3'UTR 2, Translation Start Site 1, Splice Region 1, RNA 1, Frame Shift Del 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 31/512 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 184/629 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 104/439 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525857, COSV52661319, COSV52679535, COSV53326529; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3094C>G p.Q1032E | Missense Mutation (SNP) | VAF 41/345 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV99685036; called by muse, mutect2, varscan2
- ACTRT3 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778206535, COSV100377478; called by muse, mutect2, varscan2
- ALPK2 | c.3925G>A p.D1309N | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64492460, COSV64493396; called by muse, mutect2, varscan2
- ASTL | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 25/288 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV60903866; called by muse, mutect2
- BIRC6 | c.2547C>G p.I849M | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1363253445; called by muse, mutect2, varscan2
- CD1E | c.724G>T p.V242L | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs1413340514; called by muse, mutect2
- CLIP2 | c.3131A>G p.D1044G | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV56278241; called by muse, mutect2
- DCC | c.3705G>T p.M1235I | Missense Mutation (SNP) | VAF 59/324 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV71439833; called by muse, mutect2, varscan2
- DIP2A | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs1158766248; called by muse, mutect2, varscan2
- DNAH7 | c.5237G>C p.R1746T | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56786912; called by muse, mutect2
- EHD4 | c.1442A>G p.N481S | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs776435039; called by muse, mutect2, varscan2
- EP300 | c.5296C>T p.Q1766* | Nonsense Mutation (SNP) | VAF 50/452 reads (11%) | catalogued as COSV99609259; called by muse, mutect2, varscan2
- EPHA6 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as COSV67590508; called by muse, mutect2
- FABP12 | c.387C>G p.Y129* | Nonsense Mutation (SNP) | VAF 55/265 reads (21%) | catalogued as COSV64617110; called by muse, mutect2, varscan2
- FAM120C | c.2132C>G p.S711C | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV60260429; called by muse, mutect2
- GIMAP8 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV56229625; called by muse, mutect2
- GPR32 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as rs879062227, COSV54514708; called by muse, mutect2, varscan2
- MPDZ | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as COSV59941623; called by muse, mutect2, varscan2
- MROH6 | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.414); catalogued as COSV100481752; called by muse, mutect2
- MUC17 | c.4604C>G p.S1535* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as rs780765012; called by muse, mutect2, varscan2
- MYH1 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV55441366; called by muse, mutect2
- NADK | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.137); catalogued as rs752911055; called by muse, mutect2
- OR2F2 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV68833072; called by muse, mutect2
- OR2L8 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.616); catalogued as rs1027546990; called by muse, mutect2
- PASK | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 16/479 reads (3%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as COSV99298973, COSV99299665; called by muse, mutect2
- PCDHB4 | c.95A>T p.Y32F | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.996); catalogued as rs782318038, COSV52020285; called by muse, mutect2
- PHF3 | c.3510C>G p.F1170L | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100013082; called by muse, mutect2
- PKP1 | c.1648C>A p.R550S | Missense Mutation (SNP) | VAF 62/360 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV55822822; called by muse, mutect2, varscan2
- PLXNB3 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1557059801; called by muse, mutect2, varscan2
- POMC | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV53034743, COSV53035983; called by muse, mutect2, varscan2
- PRPSAP1 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779431619; called by muse, mutect2
- RNF213 | c.1432C>A p.R478S | Missense Mutation (SNP) | VAF 31/624 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100173339, COSV100173787; called by muse, mutect2
- TENM1 | c.5496G>T p.W1832C | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM138111; called by muse, mutect2, varscan2
- TENM1 | c.5495G>C p.W1832S | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64429945; called by muse, mutect2, varscan2
- TSC22D2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100721179; called by muse, mutect2
- USP4 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 15/315 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55537598; called by muse, mutect2
- VSX2 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1027863407, COSV56218127; called by muse, mutect2
- XPO7 | c.2446C>G p.L816V | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs767966124; called by muse, mutect2, varscan2
- ZBED1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1200434388; called by muse, mutect2
- AKAP9 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 14/497 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD30A | c.3680G>A p.G1227E (on ENST00000611781; = p.G1171E on NM_052997.2) | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.087); called by muse, mutect2
- ART5 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); called by muse, mutect2
- ATP6AP2 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 54/563 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2
- ATP7A | c.3727C>A p.L1243M | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BIRC6 | c.2753C>G p.S918* | Nonsense Mutation (SNP) | VAF 21/174 reads (12%) | called by muse, mutect2, varscan2
- C10orf62 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 33/338 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- C1orf226 | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 35/396 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- C2CD4C | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CALM2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 19/194 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- CAVIN4 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CCDC168 | c.3343A>G p.K1115E | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- CCDC57 | c.2144A>T p.E715V | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CCER2 | c.161G>C p.R54T | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- CFAP61 | c.1174C>A p.L392M | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHD6 | c.4024G>C p.E1342Q | Missense Mutation (SNP) | VAF 9/259 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2
- CNTRL | c.1952A>C p.Q651P | Missense Mutation (SNP) | VAF 42/583 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2
- CRACD | c.1885C>T p.H629Y | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CSF1R | c.2446C>T p.R816C | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CSMD1 | c.7380C>A p.C2460* (on ENST00000520002; = p.C2459* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 30/380 reads (8%) | called by muse, mutect2
- DDN | c.329A>G p.Q110R | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DIDO1 | c.2942C>T p.S981F | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.642); called by muse, mutect2
- DMD | c.3871A>G p.T1291A | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DNAJC21 | c.876A>C p.E292D | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- FAM219B | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCHSD2 | c.121A>T p.T41S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.033); called by muse, mutect2
- FKTN | c.283C>G p.H95D | Missense Mutation (SNP) | VAF 9/274 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- FST | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 22/522 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HMCN1 | c.4934T>A p.L1645* | Nonsense Mutation (SNP) | VAF 15/217 reads (7%) | called by muse, mutect2
- HRH2 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 45/504 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.115); called by muse, mutect2
- IZUMO3 | c.316C>A p.Q106K | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- KCNH7 | c.2042T>C p.L681P | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- KDM2A | c.2178C>G p.I726M | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- KIAA1841 | c.1212G>A p.Q404= | Splice Region (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- KLHL41 | c.1245T>A p.D415E | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2
- KNL1 | c.5286G>C p.K1762N (on ENST00000346991 / NM_170589.5; = p.K1736N on NM_144508.5) | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2
- LIN54 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 25/251 reads (10%) | called by muse, mutect2
- LRRC24 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- MAPKBP1 | c.2416C>T p.L806F (on ENST00000456763 / NM_001128608.2; = p.L800F on NM_014994.3) | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.035); called by muse, mutect2
- MUC17 | c.12305C>A p.T4102N | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2
- MYH9 | c.3838-1G>A p.X1280_splice | Splice Site (SNP) | VAF 27/242 reads (11%) | called by muse, mutect2, varscan2
- NEO1 | c.1178A>G p.H393R | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- NR0B1 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 45/332 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- NR1H2 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2
- NUP214 | c.3106G>A p.A1036T | Missense Mutation (SNP) | VAF 32/459 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.033); called by muse, mutect2
- OR5M1 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 40/460 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- P2RY8 | c.885T>G p.F295L | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2
- PLEKHA4 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2
- PPP4R3C | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 11/164 reads (7%) | called by muse, mutect2
- RAB3IL1 | c.1020C>A p.F340L | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SEC16A | c.6812C>T p.S2271L | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- SEPTIN4 | c.822C>A p.F274L | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SLC44A1 | c.1765A>G p.I589V | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SPTB | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 44/574 reads (8%) | called by muse, mutect2
- SUPT3H | c.28A>G p.N10D | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); called by muse, mutect2
- SVEP1 | c.5577G>C p.E1859D | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- SYTL3 | c.1162del p.V388* (on ENST00000611299 / NM_001242394.1; = p.V320* on NM_001009991.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/150 reads (23%) | called by mutect2, pindel, varscan2
- TRIM14 | c.453C>A p.C151* | Nonsense Mutation (SNP) | VAF 44/458 reads (10%) | called by muse, mutect2
- TRPM3 | c.4995C>G p.D1665E (on ENST00000357533 / NM_001366142.2; = p.D1520E on NM_020952.6) | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- TTC30B | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 29/305 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.018); called by muse, mutect2
- TYMP | c.945G>A p.W315* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- UPK1B | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 46/484 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.019); called by muse, mutect2
- USP7 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.176); called by muse, mutect2
- VASN | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 34/369 reads (9%) | called by muse, mutect2
- ZFHX3 | c.41A>G p.N14S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF320 | c.1128G>C p.Q376H | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- ZNF675 | c.720C>G p.F240L | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACER2 | c.451C>T p.L151= | Silent (SNP) | VAF 28/250 reads (11%) | called by muse, varscan2
- ADAM23 | c.1599C>T p.S533= | Silent (SNP) | VAF 8/224 reads (4%) | called by muse, mutect2
- BABAM2 | c.1002C>T p.T334= | Silent (SNP) | VAF 14/308 reads (5%) | called by muse, mutect2
- CCDC158 | c.882C>A p.A294= | Silent (SNP) | VAF 46/218 reads (21%) | called by muse, mutect2, varscan2
- CCT6A | c.1548C>G p.L516= | Silent (SNP) | VAF 21/701 reads (3%) | catalogued as COSV51905893; called by muse, mutect2
- CELF6 | c.903C>T p.S301= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as rs756326200; called by muse, mutect2
- CEP295 | c.339G>A p.R113= | Silent (SNP) | VAF 8/249 reads (3%) | called by muse, mutect2
- CYP21A2 | c.1413C>T p.I471= | Silent (SNP) | VAF 80/562 reads (14%) | catalogued as rs1366459098; called by muse, mutect2, varscan2
- DDC | c.108G>A p.G36= | Silent (SNP) | VAF 49/789 reads (6%) | catalogued as rs760738743; called by muse, mutect2
- DMGDH | c.2178C>T p.A726= | Silent (SNP) | VAF 19/394 reads (5%) | called by muse, mutect2
- DNAH11 | c.1203T>C p.A401= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as rs781498100; called by mutect2, varscan2
- ELMO1 | c.252C>T p.N84= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as rs374626896; called by muse, mutect2
- FNBP1 | c.1611G>T p.T537= | Silent (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- GDI2 | c.375A>G p.E125= | Silent (SNP) | VAF 26/142 reads (18%) | called by muse, mutect2, varscan2
- HDC | c.618G>A p.V206= | Silent (SNP) | VAF 16/488 reads (3%) | catalogued as COSV51068278; called by muse, mutect2
- KATNIP | c.213C>T p.V71= | Silent (SNP) | VAF 39/325 reads (12%) | called by muse, mutect2, varscan2
- KCNH7 | c.2044C>A p.R682= | Silent (SNP) | VAF 16/251 reads (6%) | catalogued as rs374177414, COSV59815575; called by muse, mutect2
- KRT28 | c.738G>A p.E246= | Silent (SNP) | VAF 29/306 reads (9%) | called by muse, mutect2
- LHFPL1 | c.351A>T p.G117= | Silent (SNP) | VAF 24/107 reads (22%) | called by muse, varscan2
- LRRC17 | c.171C>T p.Y57= | Silent (SNP) | VAF 45/237 reads (19%) | called by muse, mutect2, varscan2
- LYPD5 | c.384G>T p.P128= (on ENST00000377950 / NM_001031749.3; = p.P85= on NM_182573.2) | Silent (SNP) | VAF 23/169 reads (14%) | called by muse, mutect2, varscan2
- MEP1A | c.765A>C p.R255= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- NPTX1 | c.165G>A p.R55= | Silent (SNP) | VAF 31/375 reads (8%) | catalogued as rs949813755; called by muse, mutect2
- NR0B1 | c.573G>A p.R191= | Silent (SNP) | VAF 46/337 reads (14%) | called by muse, mutect2, varscan2
- OR10J3 | c.705G>A p.Q235= | Silent (SNP) | VAF 27/572 reads (5%) | catalogued as COSV59955100; called by muse, mutect2
- OR1S1 | c.732A>C p.T244= | Silent (SNP) | VAF 15/243 reads (6%) | called by muse, mutect2
- PCDHB11 | c.2064C>G p.V688= | Silent (SNP) | VAF 70/476 reads (15%) | called by muse, mutect2, varscan2
- PDZD8 | c.627C>T p.D209= | Silent (SNP) | VAF 49/362 reads (14%) | catalogued as rs1299777596; called by muse, mutect2, varscan2
- PLEC | c.11682G>T p.L3894= (on ENST00000322810 / NM_201380.4; = p.L3784= on NM_000445.5) | Silent (SNP) | VAF 16/353 reads (5%) | called by muse, mutect2
- PRAMEF4 | c.1284C>G p.L428= | Silent (SNP) | VAF 59/562 reads (10%) | catalogued as rs1187557330; called by muse, mutect2, varscan2
- RHOT2 | c.381C>A p.S127= | Silent (SNP) | VAF 62/276 reads (22%) | called by muse, mutect2, varscan2
- SCARB1 | c.939C>T p.I313= | Silent (SNP) | VAF 37/306 reads (12%) | called by muse, mutect2, varscan2
- SHANK3 | c.4590C>T p.F1530= | Silent (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- SLC22A6 | c.63C>A p.V21= | Silent (SNP) | VAF 11/256 reads (4%) | called by muse, mutect2
- SLC6A16 | c.2163A>G p.L721= | Silent (SNP) | VAF 79/230 reads (34%) | called by muse, mutect2, varscan2
- SND1 | c.2673C>T p.N891= | Silent (SNP) | VAF 17/238 reads (7%) | called by muse, mutect2
- SOCS7 | c.1095C>G p.T365= | Silent (SNP) | VAF 53/367 reads (14%) | catalogued as rs587597197; called by muse, varscan2
- SPOCK3 | c.1089C>T p.D363= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as rs112005906, COSV62736405; called by muse, mutect2, varscan2
- SRCIN1 | c.1026G>A p.P342= (on ENST00000621492; = p.P308= on NM_025248.3) | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs940017597; called by muse, mutect2
- TYW3 | c.60C>T p.L20= | Silent (SNP) | VAF 25/297 reads (8%) | catalogued as rs1293025026, COSV61718231; called by muse, mutect2
- ZAP70 | c.738C>T p.L246= | Silent (SNP) | VAF 42/456 reads (9%) | called by muse, mutect2
- ZNF148 | c.633G>A p.K211= | Silent (SNP) | VAF 36/206 reads (17%) | called by muse, mutect2, varscan2
- ANKRD30BL | c.614+1007G>A | Intron (SNP) | VAF 12/188 reads (6%) | catalogued as rs1205392010, COSV54613042; called by muse, mutect2
- ATG4A | c.121+611G>T | Intron (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- CENPX | c.36+41C>G | Intron (SNP) | VAF 13/306 reads (4%) | called by muse, mutect2
- COL6A1 | c.1822+24G>C | Intron (SNP) | VAF 98/391 reads (25%) | called by muse, mutect2, varscan2
- EHMT1 | c.*15C>T | 3'UTR (SNP) | VAF 9/136 reads (7%) | catalogued as rs1039440761; called by muse, mutect2
- FAM227B | c.441+381C>T | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as rs1160906769; called by muse, mutect2, varscan2
- GGNBP1 | n.924G>A | RNA (SNP) | VAF 69/338 reads (20%) | called by muse, mutect2, varscan2
- HESX1 | c.-6G>A | 5'UTR (SNP) | VAF 28/356 reads (8%) | catalogued as rs368171529; ClinVar: uncertain significance; called by muse, mutect2
- HSF4 | c.1254+41G>A | Intron (SNP) | VAF 9/235 reads (4%) | called by muse, mutect2
- LENG8 | c.*2622G>A | 3'UTR (SNP) | VAF 10/212 reads (5%) | catalogued as rs758908650, COSV100002812; called by muse, mutect2
- MGAT4C | c.-100C>T | 5'UTR (SNP) | VAF 16/211 reads (8%) | called by muse, mutect2
- MYO19 | c.894+756G>T | Intron (SNP) | VAF 21/201 reads (10%) | called by muse, mutect2, varscan2
- PCBP2 | c.375+474C>T | Intron (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- RGMA | c.15-665G>A | Intron (SNP) | VAF 16/235 reads (7%) | called by muse, mutect2
- SLCO4A1 | chr20:62642080 del G | 5'Flank (DEL) | VAF 18/58 reads (31%) | called by mutect2, pindel, varscan2
- UBE3C | c.2003-64A>C | Intron (SNP) | VAF 32/136 reads (24%) | called by mutect2, varscan2
- UNC13C | c.4933+1864A>T | Intron (SNP) | VAF 24/182 reads (13%) | called by muse, mutect2, varscan2
- WT1 | c.1303+19C>T | Intron (SNP) | VAF 42/422 reads (10%) | called by muse, mutect2, varscan2
- ZNF333 | c.424-34G>C | Intron (SNP) | VAF 34/290 reads (12%) | called by muse, mutect2, varscan2
